Somatic mutation profile of tumor specimen TARGET-10-PARHES-09A (aliquot TARGET-10-PARHES-09A-01D) from TARGET case TARGET-10-PARHES, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,698 days).
Specimen TARGET-10-PARHES-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e01f78f-4829-4b9e-8dea-fe85a28edbb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARHES-14A (Bone Marrow Normal), aliquot TARGET-10-PARHES-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/138304c5-73be-4a5c-8eb7-da15b5a9d421

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1275G>C p.W425C (on ENST00000281708 / NM_001349798.2; = p.W345C on NM_018315.5) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55897059, COSV55897672, COSV55906595; called by muse, mutect2, varscan2
- HCN4 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs1304145729, COSV56081640; called by muse, mutect2, varscan2
- KRT36 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as rs1413433362, COSV60202604; called by mutect2, varscan2
- NEFM | c.2264T>C p.V755A | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV55330676; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- NUAK1 | c.1166C>A p.P389Q | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV54600847; called by muse, mutect2, varscan2
- NUGGC | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs964524238, COSV58432662; called by muse, mutect2, varscan2
- SHISA2 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60110194; called by muse, mutect2, varscan2
- USP32 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs768752626, COSV100342514; called by muse, mutect2, varscan2
- GANC | c.2411G>T p.S804I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- LAMA5 | c.2721G>A p.A907= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1386838441, COSV53358119; called by muse, mutect2, varscan2
- MAGI1 | c.708G>A p.A236= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs112374307; called by muse, mutect2
- TJP2 | c.771C>T p.Y257= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs769625993; called by muse, mutect2, varscan2
- HDDC3 | c.410-16G>A | Intron (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- SORL1 | c.3461-445_3461-444insCGGT | Intron (INS) | VAF 8/19 reads (42%) | called by mutect2, pindel*
- ZCCHC7 | c.610+59930C>T | Intron (SNP) | VAF 14/30 reads (47%) | catalogued as rs576481300; called by muse, mutect2, varscan2
